Surgical pathology report (de-identified scan), TCGA case TCGA-FG-6690, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-6690-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Addendum Present

Name
Accession #:
Date of Procedure: [REDACTED]
Date Received: [REDACTED]
Submitting Physician:

Med. Rec #.
Location:
Race: [REDACTED]
DOB/Sex: [REDACTED]

FINAL DIAGNOSIS

A. AND B. LEFT FRONTAL TUMOR, BIOPSY AND EXCISION:
--OLIGODENDROGLIOMA (WHO GRADE II), SEE NOTE.

Note: Analysis for allelic loss on chromosomes 1p and 19q will be performed and the results reported in an addendum.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Touch imprint and microscopic: Glioma, favor oligodendroma

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Status: Signed Out

Addendum Diagnosis

{Not Entered}

Addendum Comment

FISH FOR 1P/19Q

Date Ordered: [REDACTED]
Date Completed: [REDACTED]
Specimen Source: LEFT FRONTAL TUMOR, BIOPSY AND EXCISION
Paraffin Block No.: [REDACTED]

TUMOR TISSUE ASSESSMENT

RESULTS

Chromosome 1p: Intact, aneusomic
Chromosome 19q: Intact, eusomic

Quantitative FISH results

1p36:3.3
1q25:3.2
1p36/1q25 ratio: 1.0

19q13:2.0
19q13: 2.5
19q13/19p13 ratio: 0.8

INTERPRETATION

[page 2 of 3]
[REDACTED]

1p intact: A majority of nuclei showed similar numbers of 1p36 and 1q25 signals. There is no evidence of allelic loss on the short arm of chromosome 1 (1p).

19q intact: A majority of nuclei showed similar numbers of 19q13 and 19p13 signals. There is no evidence of allelic loss of 19q.

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the allele.

Comment:

Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss,

[REDACTED]

Method:

The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13) (Abbott Molecular/Vysis, des Plaines, IL). The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7./ Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the Pathology and Laboratory Medicine Institute at [REDACTED]. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

NOTE: One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASRs). ASRs have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the [REDACTED]). A copy of their report is on file in the Department of Anatomic Pathology [REDACTED]

[REDACTED]

[REDACTED]

Clinical History:

Left temporal tumor

Specimens Submitted As:

A: LEFT FRONTAL TUMOR
B: LEFT FRONTAL TUMOR

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number and "left frontal tumor", are multiple pink-white soft tissue fragments, 0.5 x 0.4 x 0.3 cm in aggregate. Representative tissue is submitted for touch imprint and frozen section. The remainder of the specimen is submitted entirely for permanent in 2 cassettes.

[page 3 of 3]
B: Received fresh, post fixed in formalin, labeled with the patient's name and number, are multiple irregular, opaque white to tan to brown, soft tissue fragments measuring in aggregate 2.2 x 2.1 x 0.25 cm. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file b1153f58-22df-4971-8fda-b1581fa25ec9 (TCGA-FG-6690.D4C3D026-59A3-4B34-9D49-AFD53D2D783D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).